Somatic mutation profile of tumor specimen MP2PRT-PAVIGV-TMP1-A (aliquot MP2PRT-PAVIGV-TMP1-A-1-0-D-A819-36) from MP2PRT case MP2PRT-PAVIGV, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.6 years (945 days).
Specimen MP2PRT-PAVIGV-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0b8d6ed2-6ac5-4122-900b-6ffb7814a724.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVIGV-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVIGV-NB1-A-1-0-D-A819-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/425bab6c-d0f6-4d3e-b4b6-1f0678de4408

The open-access MAF lists 5 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 silent.
By variant classification: Silent 1, Frame Shift Ins 1, Missense Mutation 1, In Frame Ins 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IGF1 | c.328G>A p.A110T | Missense Mutation (SNP) | VAF 16/256 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1280732914, COSV61034362; called by muse, mutect2
- ENTPD7 | c.1691_1692insAGGGA p.I565Gfs*35 | Frame Shift Ins (INS) | VAF 62/313 reads (20%) | called by mutect2, pindel, varscan2
- IGHV3-53 | c.349_350insTTAGGGAG | In Frame Ins (INS) | VAF 18/101 reads (18%) | called by pindel, varscan2
- IGLV4-69 | c.357_359del p.I119del | In Frame Del (DEL) | VAF 21/78 reads (27%) | called by mutect2, pindel*
- PTER | c.90C>A p.A30= | Silent (SNP) | VAF 72/355 reads (20%) | called by muse, mutect2, varscan2
